Surgical pathology report (de-identified scan), TCGA case TCGA-KM-8443, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-8443-01A (Primary Tumor).

[page 1 of 3]
DIAGNOSIS:

1. Lymph node, interaorta caval (excision): Lymph nodes, no tumor seen (0/2).
2. Kidney and adrenal, right (nephrectomy and adrenalectomy): Renal cell carcinoma, chromophobe type, Fuhrman nuclear grade III. Tumor infiltrates the capsule but does not involve the inked margin. :
Vascular and ureteral margins are free of tumor.
- Adrenal gland, no tumor seen.

Kidney Nephrectomy Summary Table Macroscopic

Specimen Type: Radical nephrectomy
Laterality: Right

Tumor Size: 12 cm in greatest dimension
Focality: Unifocal

Macro Extent of Tumor: Within inked margin

Microscopic

Histologic Type: Chromophone renal carcinoma
Histologic Grade: Fuhrman nuclear grade III

Extent of Invasion

Primary Tumor(pT): T2
Regional Lymph Nodes(pN): N0
Distant Metastasis(pM): MX

Patient Identification

[page 2 of 3]
[REDACTED]

Margins: Vascular and ureteral margins are free of tumor

CLINICAL INFORMATION: Brief Clinical History: history of large 10cm upper pole renal mass.
Tiny interaortocaval node seen on CT scan [REDACTED]

PROCEDURE: Operative Findings: Large mass with questionable involvement of adrenal. Small node identified and removed I.A.C. Post-Operative
Diagnosis: right renal mass Pre-Operative Diagnosis: right renal mass

SPECIMENS SUBMITTED: 1. LYMPH NODES, Interaortocaval node
2. KIDNEY, RIGHT, and adrenal gland

GROSS DESCRIPTION: Received are 2 containers labeled with the patient's name, medical record number, and further described as follows:

1. "Interaorta caval node". The specimen consists of 2 firm yellow and tan nodules measuring 2.0 x 1.2 x 0.6 and 0.7 x 0.5 x 0.3 cm. Both nodules are bisected revealing a smooth tan cut surface. The specimen is entirely submitted in a white cassette labeled [REDACTED] for permanent processing.
2. "Right kidney and right adrenal gland". The specimen is a radical nephrectomy specimen measuring 17 x 11 x 8 cm overall. The specimen is partially inked black and bivalved, revealing a brown tumor mass measuring 12 cm in largest dimension with a tan, soft cut surface and areas of necrosis. Approximately 3 x 1 x 0.5 cm in aggregate of the mass and approximately 1 x 1 x 0.3 cm of normal kidney is procured for [REDACTED]. Grossly, the tumor is not invading out of capsule. Gross photos taken. Procurement was performed by [REDACTED]. In Surgical Pathology, the specimen is further inked and serially sectioned. The vascular and ureteral margins are identified and submitted in white cassette #2A for permanent processing.
The tumor measures approximately 11 cm x 12 cm x 10.5 cm.
After fixation, the specimen weighs 722 grams. Sections of the tumor and the black inked specimen margin are submitted 2B, 2C, 2D, and 2E.
Representative section of tumor is submitted in 2F.
Representative section of tumor and inked specimen margin are submitted in 2G, 2H.
Two representative sections of tumor are submitted in 2I, 2J.
Two representative sections of uninvolved kidney are submitted in 2K, 2L.

Patient Identification

[page 3 of 3]
Two representative sections of the adrenal are submitted in 2M, 2N.
Representative sections of tumor and capsule are submitted in #2O, 2P, 2Q.

Gross description dictated by [REDACTED] Additional gross description dictated by [REDACTED]

No consultants

[REDACTED]

[REDACTED]

[REDACTED]

Patient Identification

[REDACTED]

Source: NCI Genomic Data Commons file 90eeddbc-896a-4f84-b168-11a2d38ed69f (TCGA-KM-8443.1BEA0219-8760-4808-B36B-08616599A76D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).